Somatic mutation profile of tumor specimen MMRF_1202_1_BM_CD138pos (aliquot MMRF_1202_1_BM_CD138pos_T1_KAS5U_L01370) from MMRF case MMRF_1202, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.8 years (21,838 days).
Specimen MMRF_1202_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 422eee9d-255c-4673-8212-1b441e2167de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1202_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1202_1_PB_Whole_C2_KAS5U_L01382; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4abbd0b-a059-4827-964d-56c2de7ad15e

The open-access MAF lists 140 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 40, Silent 14, Intron 14, 5'UTR 9, 3'Flank 5, RNA 3, Nonsense Mutation 3, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*1476G>T | 3'UTR (SNP) | VAF 35/84 reads (42%) | catalogued as rs397515514, CM084810, CM990597, COSV53411338; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANO5 | c.2699T>A p.M900K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV61084057; called by muse, varscan2
- CCDC154 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.423); catalogued as rs1323438811; called by muse, mutect2, varscan2
- CHRNB3 | c.1060G>T p.D354Y | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1431365106, COSV51494712; called by muse, mutect2, varscan2
- CYP2E1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53313213; called by muse, mutect2, varscan2
- DHX36 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.029); catalogued as rs773934907; called by muse, mutect2, varscan2
- DIS3 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705833; called by muse, mutect2
- DLGAP3 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs766267134, COSV52392724; called by muse, mutect2, varscan2
- H4C5 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as rs755041622, COSV63486069; called by muse, mutect2, varscan2
- HMCN1 | c.11513G>A p.R3838K | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54916894; called by muse, mutect2, varscan2
- IGHV2-70 | c.64A>C p.T22P | Missense Mutation (SNP) | VAF 55/57 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs755395069; called by muse, mutect2, varscan2
- MPI | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs374817183; called by muse, mutect2, varscan2
- MYH2 | c.4981A>C p.I1661L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201263691; called by muse, mutect2, varscan2
- PCDH8 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as rs772497615, COSV100131505; called by muse, mutect2
- PDE2A | c.2212C>T p.L738F | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57803255; called by muse, mutect2, varscan2
- PLB1 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771867690, COSV59836880; called by muse, mutect2, varscan2
- PWWP3B | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61800305; called by muse, mutect2, varscan2
- RASA1 | c.2308T>A p.L770I | Missense Mutation (SNP) | VAF 87/167 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.801); catalogued as rs753915358; called by muse, mutect2, varscan2
- RGS9 | c.1725G>T p.K575N | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.198); catalogued as COSV99288262; called by muse, mutect2, varscan2
- UMODL1 | c.1493T>C p.I498T | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs770991281; called by muse, mutect2, varscan2
- ZDHHC8 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 77/79 reads (97%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as rs374722785; called by muse, mutect2, varscan2
- ANO6 | c.666A>C p.Q222H | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CELF5 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- DIS3 | c.1685G>A p.C562Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DIS3 | c.824T>G p.I275R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DPF3 | c.645C>A p.Y215* | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- FMN1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- GGA2 | c.1831G>T p.G611C | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- GRIA2 | c.365A>G p.H122R | Missense Mutation (SNP) | VAF 239/481 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- HCRTR1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.014); called by muse, mutect2
- IGHV1-69D | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by mutect2, varscan2
- ITGB3 | c.1906T>A p.F636I | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC29 | c.352T>G p.L118V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MZF1 | c.1178T>C p.F393S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NPAT | c.1679T>G p.L560R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PBX4 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PKHD1 | c.10576T>A p.L3526M | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- POGZ | c.1211A>C p.Y404S | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PTCHD1 | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PYROXD1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- RICTOR | c.4241C>T p.S1414F | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNF19A | c.2374T>G p.L792V | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF213 | c.4754T>G p.V1585G | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SLC38A9 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SLC6A11 | c.397_398insTC p.G133Vfs*7 | Frame Shift Ins (INS) | VAF 73/170 reads (43%) | called by mutect2, pindel*, varscan2*
- SMPD1 | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 92/194 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SNX1 | c.509A>C p.Q170P | Missense Mutation (SNP) | VAF 117/251 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TASOR2 | c.6550A>T p.T2184S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TBC1D32 | c.1484G>A p.S495N | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- USP35 | c.2797G>C p.A933P | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- VIT | c.1810A>T p.R604W (on ENST00000389975 / NM_001177969.1; = p.R619W on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBED6 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZFPM2 | c.3298C>T p.Q1100* | Nonsense Mutation (SNP) | VAF 53/107 reads (50%) | called by muse, mutect2, varscan2
- ZNF318 | c.3108G>T p.K1036N | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CEBPZ | c.636G>C p.L212= | Silent (SNP) | VAF 95/205 reads (46%) | called by muse, mutect2, varscan2
- CLDN7 | c.277C>T p.L93= | Silent (SNP) | VAF 55/114 reads (48%) | called by muse, mutect2, varscan2
- DCDC2 | c.1311C>T p.G437= | Silent (SNP) | VAF 65/166 reads (39%) | called by muse, mutect2, varscan2
- FABP4 | c.318G>A p.K106= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as rs1315506569; called by muse, mutect2, varscan2
- FAT1 | c.5127T>C p.A1709= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- FGGY | c.76C>T p.L26= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- MTHFD2L | c.288T>C p.H96= (on ENST00000395759 / NM_001144978.2; = p.H38= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- PAK5 | c.345C>T p.H115= | Silent (SNP) | VAF 63/119 reads (53%) | catalogued as rs780125410, COSV62027678; called by muse, mutect2, varscan2
- RASEF | c.315C>T p.D105= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- RP1L1 | c.3450G>A p.L1150= | Silent (SNP) | VAF 90/172 reads (52%) | catalogued as COSV66754689; called by muse, mutect2
- SERPINB11 | c.1029C>T p.G343= | Silent (SNP) | VAF 68/140 reads (49%) | called by muse, mutect2, varscan2
- SLC30A6 | c.18C>T p.L6= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV50872124; called by muse, varscan2
- THOC5 | c.1335G>A p.Q445= | Silent (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2, varscan2
- ZNF676 | c.375G>A p.V125= (on ENST00000650058; = p.V93= on NM_001001411.3) | Silent (SNP) | VAF 53/112 reads (47%) | called by muse, mutect2, varscan2
- AC245033.1 | c.155-4282G>A | Intron (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- AGPAT4 | c.348+5206C>T | Intron (SNP) | VAF 68/137 reads (50%) | catalogued as rs1167806861; called by muse, mutect2, varscan2
- ANO5 | c.*25T>A | 3'UTR (SNP) | VAF 48/108 reads (44%) | called by muse, varscan2
- APOBEC3B | c.-38A>C | 5'UTR (SNP) | VAF 120/231 reads (52%) | catalogued as COSV59841889; called by muse, mutect2, varscan2
- ATG16L1 | c.-153A>G | 5'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2
- BMP6 | c.*1093_*1119del | 3'UTR (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel
- C10orf53 | c.217+246G>A | Intron (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- C16orf72 | c.*3966T>A | 3'UTR (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2
- C16orf72 | c.*3968T>A | 3'UTR (SNP) | VAF 32/69 reads (46%) | catalogued as rs536693517; called by muse, mutect2
- C17orf100 | c.-58G>T | 5'UTR (SNP) | VAF 34/56 reads (61%) | called by muse, mutect2, varscan2
- CEP170P1 | n.2267A>C | RNA (SNP) | VAF 41/79 reads (52%) | called by mutect2, varscan2
- CHAF1B | c.*286G>A | 3'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- CLCN3 | c.*2398T>G | 3'UTR (SNP) | VAF 63/115 reads (55%) | called by muse, mutect2, varscan2
- COQ3 | c.*107T>A | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- CRNKL1 | c.-24C>A | 5'UTR (SNP) | VAF 170/356 reads (48%) | called by muse, mutect2, varscan2
- DAAM1 | c.*1245T>G | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- DIRAS2 | c.*114T>A | 3'UTR (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- DMRTA1 | c.*597T>A | 3'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- E2F7 | c.*880C>T | 3'UTR (SNP) | VAF 66/152 reads (43%) | called by muse, mutect2, varscan2
- ETS1 | chr11:128460636 T>C | 3'Flank (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- FAM133B | c.*1219T>C | 3'UTR (SNP) | VAF 36/95 reads (38%) | called by muse, mutect2, varscan2
- FAM135B | c.*621G>A | 3'UTR (SNP) | VAF 46/125 reads (37%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1255C>T | 3'UTR (SNP) | VAF 24/44 reads (55%) | catalogued as rs569462075; called by muse, mutect2, varscan2
- FGFR3 | chr4:1808248 G>A | 3'Flank (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- GARS1 | chr7:30594730 A>G | 5'Flank (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- GLRA3 | c.*2397T>G | 3'UTR (SNP) | VAF 5/105 reads (5%) | called by muse, mutect2
- GRIN3A | c.*943C>T | 3'UTR (SNP) | VAF 63/114 reads (55%) | called by muse, mutect2, varscan2
- GUCY1B1 | c.78-2285G>C | Intron (SNP) | VAF 65/137 reads (47%) | called by muse, mutect2, varscan2
- HDAC2 | c.*6096G>C | 3'UTR (SNP) | VAF 51/104 reads (49%) | catalogued as rs1186084475; called by muse, mutect2, varscan2
- HHIP | c.*5113G>A | 3'UTR (SNP) | VAF 49/104 reads (47%) | catalogued as rs982396787; called by muse, mutect2, varscan2
- HMGA2 | c.282+3385C>T | Intron (SNP) | VAF 30/71 reads (42%) | catalogued as rs934392438, COSV66913601; called by muse, mutect2, varscan2
- HNRNPU | chr1:244851209 A>G | 3'Flank (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- IGHV3-21 | c.-7A>G | 5'UTR (SNP) | VAF 73/167 reads (44%) | catalogued as rs782068951; called by muse, mutect2, varscan2
- LDLRAD2 | c.*2208G>C | 3'UTR (SNP) | VAF 31/53 reads (58%) | called by muse, mutect2, varscan2
- LGR6 | c.1137-64G>A | Intron (SNP) | VAF 23/68 reads (34%) | catalogued as rs775749802; called by muse, mutect2, varscan2
- LIFR | c.*2979A>T | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- MKRN9P | n.829G>T | RNA (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- MMP17 | c.*299C>T | 3'UTR (SNP) | VAF 8/80 reads (10%) | catalogued as rs1375415217; called by muse, mutect2
- MOCOS | c.*2011A>C | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- NEO1 | c.*1073G>C | 3'UTR (SNP) | VAF 17/39 reads (44%) | catalogued as rs999156729; called by muse, mutect2, varscan2
- ONECUT2 | c.*11486A>G | 3'UTR (SNP) | VAF 58/118 reads (49%) | catalogued as rs1185884353; called by muse, mutect2, varscan2
- OTUB1 | chr11:64001787 G>A | 3'Flank (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- PAH | c.*784T>A | 3'UTR (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- PARD3B | c.*3343A>G | 3'UTR (SNP) | VAF 45/91 reads (49%) | called by muse, mutect2, varscan2
- PDE7B | c.*1394T>A | 3'UTR (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- PDGFD | c.*2110_*2113del | 3'UTR (DEL) | VAF 47/97 reads (48%) | called by pindel, varscan2
- PDIK1L | c.*2107G>A | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- PEMT | c.-50_-49insT | 5'UTR (INS) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- PEX5L | c.*1028A>G | 3'UTR (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- PFAS | c.*623T>A | 3'UTR (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- PIAS3 | c.*807C>T | 3'UTR (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- PPARGC1A | c.234+162G>A | Intron (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- PRDM15 | c.-723T>C | 5'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- PRDM5 | c.*2685C>T | 3'UTR (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- PTGER3 | c.1077+2262T>A | Intron (SNP) | VAF 69/122 reads (57%) | catalogued as rs1040429086; called by muse, mutect2, varscan2
- PTRH2 | c.1-1952G>A | Intron (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- PXN | chr12:120210434 G>A | 3'Flank (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- PXYLP1 | c.79+2127A>G | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- RASGEF1B | c.438+34T>A | Intron (SNP) | VAF 43/77 reads (56%) | called by muse, mutect2, varscan2
- RCOR3 | chr1:211259410 G>A | 5'Flank (SNP) | VAF 20/25 reads (80%) | called by muse, mutect2, varscan2
- RHOBTB3 | c.*2689T>G | 3'UTR (SNP) | VAF 40/103 reads (39%) | called by muse, mutect2, varscan2
- SAR1A | c.*2268_*2272del | 3'UTR (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel
- SARM1 | c.*1023T>A | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- SLAMF1 | c.*639T>A | 3'UTR (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- SLC25A36 | c.385+208T>A | Intron (SNP) | VAF 38/84 reads (45%) | called by muse, mutect2, varscan2
- SLC66A1L | n.558A>T | RNA (SNP) | VAF 175/360 reads (49%) | catalogued as COSV101456719; called by muse, mutect2, varscan2
- SNAP91 | c.-30-133G>C | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- STRADB | c.1071-67T>G | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- SURF4 | c.-57G>A | 5'UTR (SNP) | VAF 5/11 reads (45%) | catalogued as rs938055270; called by muse, mutect2, varscan2
- TMEM65 | c.-337C>G | 5'UTR (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- TMTC3 | c.*1635T>C | 3'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, varscan2
- WBP4 | c.*298T>C | 3'UTR (SNP) | VAF 50/50 reads (100%) | called by muse, mutect2, varscan2
